Somatic mutation profile of tumor specimen TCGA-3U-A98F-01A (aliquot TCGA-3U-A98F-01A-11D-A39R-32) from TCGA case TCGA-3U-A98F, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mesothelioma, biphasic, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 73.7 years (26,926 days).
Specimen TCGA-3U-A98F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 38d4d700-62dd-4d80-9fc8-2cabfe27c6c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3U-A98F-10A (Blood Derived Normal), aliquot TCGA-3U-A98F-10A-01D-A39U-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bb2d86ad-7aa6-4b59-a057-1f94712d2013

The open-access MAF lists 44 somatic variants for this specimen: 31 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 23, Silent 13, Frame Shift Del 3, Nonsense Mutation 2, Splice Region 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CANT1 | c.388A>G p.K130E | Missense Mutation (SNP) | VAF 60/144 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.171); catalogued as COSV56604836; called by muse, mutect2, varscan2
- CSMD1 | c.9767G>A p.R3256H (on ENST00000520002; = p.R3255H on NM_033225.6) | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1400192870; called by muse, mutect2, varscan2
- CYP4F2 | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as rs200373927; called by muse, mutect2, varscan2
- EDIL3 | c.304G>C p.G102R | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.661); catalogued as rs1382710811; called by muse, mutect2, varscan2
- EGR3 | c.1028C>A p.A343E | Missense Mutation (SNP) | VAF 51/115 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57833430; called by muse, mutect2, varscan2
- GLDN | c.1138T>C p.S380P | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.765); catalogued as rs1349576375; called by muse, mutect2, varscan2
- INSC | c.1441G>A p.A481T | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.73); catalogued as rs758251978; called by muse, mutect2, varscan2
- MFSD8 | c.277A>G p.I93V | Missense Mutation (SNP) | VAF 52/60 reads (87%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs578102641; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYBL2 | c.1630G>A p.D544N | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53833540; called by muse, mutect2, varscan2
- MYT1L | c.424G>T p.D142Y | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as COSV67720977; called by muse, mutect2, varscan2
- NF2 | c.999+1G>T p.X333_splice | Splice Site (SNP) | VAF 16/19 reads (84%) | catalogued as CS941521, COSV104404720, COSV58521975, COSV58525246; called by muse, mutect2, varscan2
- NLRP4 | c.596C>T p.T199M | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as rs370421219; called by muse, mutect2, varscan2
- SLC2A6 | c.1519C>A p.R507S | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.03); catalogued as COSV99390254; called by muse, mutect2, varscan2
- ZAN | c.6030C>T p.I2010= | Splice Region (SNP) | VAF 15/81 reads (19%) | catalogued as rs1257123616; called by muse, mutect2, varscan2
- ADGRV1 | c.923C>A p.T308K | Missense Mutation (SNP) | VAF 42/75 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ALPK3 | c.3902T>A p.I1301N | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- AQR | c.45_48del p.S16Kfs*7 | Frame Shift Del (DEL) | VAF 53/111 reads (48%) | called by mutect2, pindel, varscan2
- DLX2 | c.846G>C p.W282C | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- FBLN1 | c.975C>A p.C325* | Nonsense Mutation (SNP) | VAF 25/28 reads (89%) | called by muse, mutect2, varscan2
- FMNL2 | c.1215A>T p.L405F | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- GAS2L1 | c.311_324delinsG p.A104Gfs*93 | Frame Shift Del (DEL) | VAF 38/55 reads (69%) | called by pindel, varscan2*
- GXYLT2 | c.1042T>G p.C348G | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIAA0100 | c.3553G>T p.D1185Y | Missense Mutation (SNP) | VAF 81/187 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- MGAT5 | c.185C>A p.A62E | Missense Mutation (SNP) | VAF 54/106 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NSUN2 | c.1738del p.V580Lfs*52 | Frame Shift Del (DEL) | VAF 30/114 reads (26%) | called by mutect2, pindel, varscan2
- NUP210L | c.4792C>G p.P1598A | Missense Mutation (SNP) | VAF 30/179 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PDHX | c.227G>T p.W76L | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SNRPA1 | c.668_669insA p.L224Afs*17 | Frame Shift Ins (INS) | VAF 23/84 reads (27%) | called by mutect2, pindel, varscan2
- SORCS3 | c.155G>T p.R52L | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- TENM4 | c.3013G>T p.E1005* | Nonsense Mutation (SNP) | VAF 20/38 reads (53%) | called by muse, mutect2, varscan2
- ZNF396 | c.246G>T p.R82S | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- C4BPA | c.63C>A p.P21= | Silent (SNP) | VAF 36/84 reads (43%) | called by muse, mutect2, varscan2
- COL20A1 | c.3069G>A p.S1023= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as rs778232271, COSV58912923; called by muse, mutect2, varscan2
- GYS1 | c.1191G>A p.K397= | Silent (SNP) | VAF 36/52 reads (69%) | called by muse, mutect2, varscan2
- KRT72 | c.1044C>T p.R348= | Silent (SNP) | VAF 22/30 reads (73%) | called by muse, mutect2, varscan2
- OR1M1 | c.99C>T p.C33= | Silent (SNP) | VAF 47/75 reads (63%) | called by muse, mutect2, varscan2
- PLK3 | c.489C>G p.R163= | Silent (SNP) | VAF 36/43 reads (84%) | called by muse, mutect2, varscan2
- PRPF3 | c.420C>G p.L140= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV61395252; called by muse, mutect2
- RASGRF2 | c.426A>G p.V142= | Silent (SNP) | VAF 10/26 reads (38%) | called by muse, mutect2
- SEC24A | c.2184A>G p.V728= | Silent (SNP) | VAF 24/101 reads (24%) | called by muse, mutect2, varscan2
- SYT5 | c.105C>T p.I35= | Silent (SNP) | VAF 33/113 reads (29%) | called by muse, mutect2, varscan2
- TOP2A | c.9G>A p.V3= | Silent (SNP) | VAF 59/104 reads (57%) | called by muse, mutect2, varscan2
- TRANK1 | c.2550C>T p.D850= | Silent (SNP) | VAF 50/64 reads (78%) | called by muse, mutect2, varscan2
- UNC13B | c.4257T>G p.P1419= | Silent (SNP) | VAF 23/64 reads (36%) | called by muse, mutect2, varscan2
